Somatic mutation profile of tumor specimen 0DG87Q from CCDI case PBBSUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 18.8 years (6,851 days).
Specimen 0DG87Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28c59eaa-9bfc-4720-878c-28c21afaa001.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG84M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec7d4f99-7981-45a7-b994-ab12e5a1a96e

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPC1 | c.3614C>G p.T1205R | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758902805, CD030341, CM002384, CM032649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- COLEC10 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 60/589 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769900711, COSV60520610; called by muse, mutect2
- ABCD2 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- JMJD1C | c.6116A>G p.E2039G | Missense Mutation (SNP) | VAF 63/777 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- SYVN1 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2
- C15orf39 | c.1546C>T p.L516= | Silent (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2, varscan2
- DHRS7B | c.-41T>C | 5'UTR (SNP) | VAF 36/540 reads (7%) | catalogued as rs375926496; called by muse, mutect2
- HSPA12A | c.836-9G>A | Intron (SNP) | VAF 129/767 reads (17%) | catalogued as rs1298252009; called by muse, mutect2, varscan2
- PHF8 | c.2757+860G>A | Intron (SNP) | VAF 12/199 reads (6%) | called by muse, mutect2
- ZNF707 | c.142+77G>A | Intron (SNP) | VAF 5/79 reads (6%) | catalogued as rs896320034; called by muse, mutect2
